Gene-level copy-number profile of tumor specimen TCGA-N6-A4VC-01A from TCGA case TCGA-N6-A4VC, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage III; Age at diagnosis: 83.9 years (30,643 days).
Specimen TCGA-N6-A4VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.64b4d761-ab22-4d4e-bbef-015f620250d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N6-A4VC-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48092d95-2aa2-4ff7-aac6-1d26decd1244

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 782; copy number 2: 25,857; copy number 3: 19,576; copy number 4: 9,754; copy number 5: 2,709; copy number 6: 1,063; copy number 7: 44; copy number 8: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N6-A4VC-01A-11D-A28Q-01): tumor purity 0.83, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:31,676,256–32,160,392, 20 genes: PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1, AP1B1P1, Z83839.1, AP1B1P2, Z83839.2, C22orf42, AL008723.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,822 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,769,339–164,921,629, 13 genes, copy number 5: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7.
- chr1:237,555,040–240,776,824, 48 genes, copy number 5: AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,998,794, 3 genes, copy number 5: RFKP1, HNRNPA1P42, AL590682.1.
- chr2:38,814–83,657,842, 1,389 genes, copy number 5–6 (broad region; genes not listed).
- chr3:127,480,690–127,680,926, 11 genes, copy number 6: LINC01471, AC016968.1, LINC02034, AC084035.1, TPRA1, MIR6825, MIR7976, MCM2, AC023593.1, PODXL2, ABTB1.
- chr5:176,346,062–176,659,054, 19 genes, copy number 5: KIAA1191, AC138956.1, AC138956.2, ARL10, MIR1271, NOP16, HIGD2A, CLTB, AC010297.1, FAF2, RNF44, CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B, TSPAN17.
- chr8:60,876,969–120,056,201, 856 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr8:135,455,865–145,066,685, 229 genes, copy number 5 (broad region; genes not listed).
- chr10:32,446,140–32,882,874, 1 gene, copy number 5 (within-gene range 4–5): CCDC7.
- chr10:32,887,273–38,719,229, 106 genes, copy number 5–7 (broad region; genes not listed).
- chr10:68,988,803–69,043,544, 1 gene, copy number 5 (within-gene range 3–5): KIFBP.
- chr10:69,022,778–69,964,275, 27 genes, copy number 5 (within-gene range 3–5): ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1.
- chr12:66,767–44,921,848, 942 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:56,511,002–56,941,482, 18 genes, copy number 6: HSPD1P4, RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2.
- chr17:212,389–511,347, 9 genes, copy number 5 (within-gene range 2–5): RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:523,140–553,417, 2 genes, copy number 5: AC015853.3, AC015853.1.
- chr17:39,671,122–40,975,926, 68 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr17:49,700,934–50,287,855, 34 genes, copy number 7: SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1, AC027801.2, AC027801.4, AC027801.3, RNU6-1313P, DLX4, DLX3, AC009720.1, PICART1, ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1.
- chr17:67,070,444–67,366,605, 9 genes, copy number 5: HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12.
- chr17:67,408,774–67,408,881, 1 gene, copy number 5: Y_RNA.
- chr17:75,874,164–76,154,650, 21 genes, copy number 5: TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868, FOXJ1, RNF157-AS1.
- chr22:49,718,053–49,934,074, 15 genes, copy number 5: AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1.

Autosomal genes at a single copy (total copy number 1): 782. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
